Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5170, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5170-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

TCGA-BP-5170

Specimens Submitted:

1: SP: Right kidney

2: SP: Portion of right 11th (eleventh) rib

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), NUCLEAR GRADE II/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 3 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- 2) RIB, PORTION OF RIGHT ELEVENTH; RESECTION:
- BONE, CARTILAGE AND SOFT TISSUES, NEGATIVE FOR TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1) The specimen is received fresh, labeled "Right Kidney". It consists of a right nephrectomy, measuring 21 x 11 x 6 cm. On the anterior aspect a portion of the Gerota's fascia is recognized measuring 12 x 6 cm, grossly unremarkable. The perirenal fat is encasing the kidney and measures up to 2.5 cm in thickness. The ureter measures 12 cm in length and 0.3 cm in diameter. The surgical margins are inked anterior blue, posterior black. The specimen is bivalved revealing a normal, unremarkable appearance. Serial sectioning the specimen from the superior towards the inferior pole reveals a well demarcated, encapsulated, brown yellow tumor with hemorrhagic areas. The tumor is located on the middle third of the kidney on the anterior aspect. The tumor measures 3 x 3 x 2.5 cm. The capsule surrounding the tumor measures 0.1 cm in thickness. Grossly the tumor abuts the kidney capsule, pushing toward perirenal fat. The tumor extends to the renal sinus. The renal parenchyma measures up to 2.5 cm in thickness. In the hilum, renal arteries and veins are identified with a permeable lumen. The renal pelvis is covered by pink smooth mucosa. The renal ureter is patent. The specimen is representatively submitted. Tissue is submitted for EM and TPS. Photographs are taken.

Summary of Sections:

UM - ureteral margin

V - vessels from the kidney hilum

[page 2 of 2]
T – tumor
K – unremarkable kidney

2) The specimen is received in formalin, labeled "Portion of Right 11th Rib". It consists of a portion of the right 11th rib, measuring 10.3 cm in length and 1.3 cm in diameter. Grossly unremarkable. The specimen is representatively submitted following decalcification.

Summary of Sections:
S - specimen

Summary of Sections:

Part 1: SP: Right kidney

Block	Sect. Site	PCs
1	k	1
4	t	4
1	um	1
1	v	3

Part 2: SP: Portion of right 11th (eleventh) rib

Block	Sect. Site	PCs
1	s	2

Source: NCI Genomic Data Commons file f24c9f24-74b8-4265-beab-dc2ed1368a48 (TCGA-BP-5170.6C8B6B3D-F68A-448E-AF85-4BECC1625C6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).